Somatic mutation profile of tumor specimen 0DOXGW from CCDI case PBCCUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant tumor, small cell type; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,916 days).
Specimen 0DOXGW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adc9fa40-5bce-470e-bd2c-45eb29aa13ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXFZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/035b2687-6e9b-496e-ba16-f175311d4791

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND2 | c.2336C>A p.T779N | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1343108921; called by muse, mutect2
- DOLPP1 | c.680+1G>A p.X227_splice | Splice Site (SNP) | VAF 54/83 reads (65%) | catalogued as rs1409408356; called by muse, mutect2, varscan2
- OGDH | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.837); catalogued as rs1464744116, COSV56056358; called by muse, mutect2
- PTCH1 | c.1804del p.R602Dfs*21 | Frame Shift Del (DEL) | VAF 99/167 reads (59%) | catalogued as CM066203, COSV59462369, COSV59487305; called by mutect2, varscan2
- SPRY3 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.3); catalogued as rs771224871, COSV57142834; called by muse, mutect2
- UBE3B | c.2926G>A p.V976M | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746325229; called by muse, mutect2, varscan2
- ZBTB21 | c.2281G>A p.E761K | Missense Mutation (SNP) | VAF 112/244 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as rs757855811, COSV60404561; called by muse, mutect2, varscan2
- C2CD2L | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- DSC1 | c.1118T>C p.L373S | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDO1 | c.645C>G p.H215Q | Missense Mutation (SNP) | VAF 95/266 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK1 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 36/558 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2
- PTCH1 | c.2655dup p.L886Tfs*10 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | called by mutect2, varscan2
- TDRD9 | c.3620-5_3630del p.X1207_splice | Splice Site (DEL) | VAF 14/52 reads (27%) | called by mutect2, varscan2
- CFAP65 | c.1827C>T p.N609= | Silent (SNP) | VAF 60/234 reads (26%) | catalogued as rs199755213; called by muse, mutect2, varscan2
- RCBTB2 | c.1092C>T p.A364= | Silent (SNP) | VAF 94/307 reads (31%) | catalogued as rs141373575; called by muse, mutect2, varscan2
- WWC1 | c.2739G>A p.P913= | Silent (SNP) | VAF 111/212 reads (52%) | catalogued as rs747328142, COSV99515014; called by muse, mutect2, varscan2
